Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A5KF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A5KF-01A (Primary Tumor).

Gross Description: In bladder, there are an invasive and protruded tumor, ill - margins with 2.5x2x2cm in size, soft and gray surface.

Microscopic Description: Transitional cells are hyperplastic. Tumor cells arrange to form pappillary or trabeculae one by one. Tumor cells have moderate and eosinophilic cytoplasm. Nuclei are enlarged and varriability in shape and size, fairly irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in superficial muscularis propria.

Diagnosis Details: Infiltrating urothelial carcinoma, low-grade, infiltrating superficial muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 2.5 x 2 x 2 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Superficial muscle (inner half)

Lymph nodes: Not specified

Lymphatic invasion: Absent

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-6-3
Carcinoma, transitional
Cell NOS 8120/3
Site: Bladder NOS C67.9
9/21/13

HI/AA Discrepancy		

Source: NCI Genomic Data Commons file 4f56e59e-cd4e-4946-b05b-f68177208c63 (TCGA-E7-A5KF.4EE096A0-381D-468C-AA30-F914F4F6589E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).